Somatic mutation profile of tumor specimen TCGA-EL-A3D6-01A (aliquot TCGA-EL-A3D6-01A-12D-A202-08) from TCGA case TCGA-EL-A3D6, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.0 years (18,640 days).
Specimen TCGA-EL-A3D6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9623e774-186f-43e4-9761-78985b505d68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3D6-10A (Blood Derived Normal), aliquot TCGA-EL-A3D6-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f0301d8-5f0d-42b8-bea9-c39ced725f6e

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRB3 | c.2255A>T p.K752I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV65391394; called by muse, mutect2
- APOBR | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.159); catalogued as COSV60490020; called by muse, mutect2, varscan2
- CA13 | c.689T>G p.L230R | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58797576; called by muse, mutect2, varscan2
- COL4A1 | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65424245, COSV65430929; called by muse, mutect2, varscan2
- EVPL | c.1138-1G>C p.X380_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV56909801; called by muse, mutect2, varscan2
- FAM110B | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV64064616; called by muse, mutect2, varscan2
- GABRA6 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV50878657; called by muse, mutect2
- HDAC8 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV65265961; called by muse, mutect2, varscan2
- IARS1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 9/267 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as COSV65114818; called by muse, mutect2
- ITPKB | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as COSV55263679; called by muse, mutect2
- JMJD1C | c.2014A>T p.R672* | Nonsense Mutation (SNP) | VAF 24/126 reads (19%) | catalogued as COSV67860698; called by muse, mutect2, varscan2
- MIA2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV54491151, COSV54491759; called by muse, mutect2
- MRPL38 | c.843del p.S282Lfs*30 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as COSV53932279, COSV53932707; called by mutect2, pindel, varscan2
- OR13F1 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs142994537, COSV100594791; called by muse, mutect2, varscan2
- PROKR2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146544539; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINA1 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 14/160 reads (9%) | catalogued as rs1480528329, COSV63345540; called by muse, mutect2
- SIKE1 | c.360dup p.A121Sfs*5 | Frame Shift Ins (INS) | VAF 28/158 reads (18%) | catalogued as rs1163855157; called by mutect2, pindel, varscan2
- SLC8A3 | c.1906+1G>A p.X636_splice (on ENST00000381269 / NM_183002.3; = p.X637_splice on NM_033262.4) | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as rs867788110, COSV53688740; called by muse, mutect2, varscan2
- TMPRSS15 | c.295T>A p.S99T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV53038421; called by muse, mutect2
- TP53 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 7/170 reads (4%) | catalogued as rs1555524156, COSV52716070, COSV52776099; ClinVar: uncertain significance; called by muse, mutect2
- ZAN | c.3194G>T p.S1065I | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV61807940; called by muse, mutect2, varscan2
- ALS2 | c.2375del p.F792Sfs*18 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- CDH26 | c.453C>T p.F151= | Silent (SNP) | VAF 10/230 reads (4%) | catalogued as COSV54845734, COSV54854486; called by muse, mutect2
- NAALADL2 | c.1966T>C p.L656= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV71984381; called by muse, mutect2
- TSPAN32 | c.381C>T p.Y127= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs147630481, COSV51719530; called by muse, mutect2, varscan2
- SPATA8 | n.916G>A | RNA (SNP) | VAF 60/133 reads (45%) | catalogued as COSV60704517; called by muse, mutect2, varscan2
